Somatic mutation profile of tumor specimen ALCH-B0AR-TTP1-A (aliquot ALCH-B0AR-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0AR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.1 years (29,628 days).
Specimen ALCH-B0AR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b31c01e0-0bbc-44c2-b71b-a1e25cd7d09a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AR-NB1-A (Blood Derived Normal), aliquot ALCH-B0AR-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86b2f3b4-bd3d-4a1c-bf78-84a81a6406b0

The open-access MAF lists 75 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 19, Intron 6, In Frame Del 2, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 101/410 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 171/548 reads (31%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ANK1 | c.5177C>G p.T1726R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs200662932, COSV55876151; called by muse, mutect2
- ASB2 | c.735C>T p.Y245= | Splice Region (SNP) | VAF 14/74 reads (19%) | catalogued as rs779431061, COSV60112810; called by muse, mutect2
- BEND2 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs868376547, COSV66221592; called by muse, mutect2, varscan2
- BRS3 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.924); catalogued as rs780571965; called by muse, mutect2, varscan2
- CADM3 | c.733C>T p.R245C (on ENST00000368125 / NM_001127173.3; = p.R279C on NM_021189.5) | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1431857861, COSV63685009; called by muse, mutect2, varscan2
- CADPS | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV51869590; called by muse, mutect2, varscan2
- CHRNE | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 126/548 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV53418124; called by muse, mutect2, varscan2
- CTBP2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs758782963, COSV58336407; called by muse, mutect2, varscan2
- FLNA | c.4393G>A p.A1465T | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as rs1557177396; called by muse, mutect2, varscan2
- FTCD | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as rs201966668; called by muse, mutect2, varscan2
- GABRA2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as rs1196674223, COSV62916644; called by muse, mutect2, varscan2
- GAS2L3 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57156930; called by muse, mutect2, varscan2
- HDAC5 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs750672810, COSV99870516; called by muse, mutect2, varscan2
- HTT | c.3341A>C p.E1114A | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.427); catalogued as rs529839694; called by muse, mutect2, varscan2
- RYR2 | c.5557G>T p.E1853* | Nonsense Mutation (SNP) | VAF 63/338 reads (19%) | catalogued as COSV63685502, COSV63696823; called by muse, mutect2, varscan2
- SOS2 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775192786; called by muse, mutect2, varscan2
- TFEB | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs369743790, COSV57823541; called by muse, mutect2, varscan2
- ZNF181 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 13/408 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV67626209; called by muse, mutect2
- ANK3 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP1A3 | c.898G>A p.G300S (on ENST00000545399 / NM_001256214.2; = p.G287S on NM_152296.5) | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ATRNL1 | c.985T>A p.S329T | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- AVIL | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CASD1 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCNKA | c.172del p.V58Cfs*10 | Frame Shift Del (DEL) | VAF 127/507 reads (25%) | called by mutect2, pindel, varscan2
- COL6A5 | c.4400G>A p.G1467E | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DIPK2B | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMRT1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FASN | c.3409_3411del p.E1137del | In Frame Del (DEL) | VAF 67/380 reads (18%) | called by pindel, varscan2
- GFI1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLIS3 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.2085dup p.K696Qfs*82 (on ENST00000621958; = p.K695Qfs*82 on NM_001004334.4) | Frame Shift Ins (INS) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- INHBA | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MCF2L2 | c.2566C>A p.R856S | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MOS | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NSD2 | c.523T>G p.Y175D | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OBP2A | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- OR11A1 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR4M1 | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 84/502 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCDHA9 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 119/448 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PKP4 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PLEKHF2 | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SH3D21 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SRPK3 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.45); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- STYXL2 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- TM9SF3 | c.756dup p.A253Cfs*5 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | called by mutect2, pindel, varscan2
- YIPF6 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- ZNF726 | c.1396T>C p.S466P | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAMTA2 | c.3336C>T p.F1112= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as rs772954729; called by muse, mutect2, varscan2
- CASK | c.687C>T p.G229= | Silent (SNP) | VAF 57/435 reads (13%) | catalogued as rs898704533; called by muse, mutect2, varscan2
- CDT1 | c.972G>A p.P324= | Silent (SNP) | VAF 67/201 reads (33%) | catalogued as rs765182943; called by muse, mutect2, varscan2
- COL22A1 | c.1272T>C p.Y424= | Silent (SNP) | VAF 48/351 reads (14%) | catalogued as rs1438100822; called by muse, mutect2, varscan2
- DNAJC2 | c.1314G>A p.K438= | Silent (SNP) | VAF 63/258 reads (24%) | called by muse, mutect2, varscan2
- FIGNL2 | c.963G>T p.S321= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- GABRA1 | c.546A>G p.L182= | Silent (SNP) | VAF 106/464 reads (23%) | catalogued as rs747735903; called by muse, mutect2, varscan2
- GDF6 | c.594C>T p.D198= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs994022206, COSV54625159; called by muse, mutect2, varscan2
- GPT2 | c.552C>T p.T184= | Silent (SNP) | VAF 35/144 reads (24%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.1152C>T p.R384= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs767095174, COSV52372861; called by muse, mutect2, varscan2
- IL1RL2 | c.1476G>A p.E492= | Silent (SNP) | VAF 9/252 reads (4%) | catalogued as COSV51819113; called by muse, mutect2
- KNL1 | c.2391C>T p.V797= (on ENST00000346991 / NM_170589.5; = p.V771= on NM_144508.5) | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2
- LMOD3 | c.1140G>A p.P380= | Silent (SNP) | VAF 119/433 reads (27%) | catalogued as rs1269451090; called by muse, mutect2, varscan2
- PCDH11X | c.3309C>T p.R1103= | Silent (SNP) | VAF 62/277 reads (22%) | called by muse, mutect2, varscan2
- PRDM15 | c.3549G>T p.P1183= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs759648530, COSV54148982; called by mutect2, varscan2
- SPTBN4 | c.1288C>T p.L430= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as rs774379566; called by muse, mutect2, varscan2
- SRGAP3 | c.702G>A p.L234= | Silent (SNP) | VAF 82/313 reads (26%) | called by muse, mutect2, varscan2
- VWA3A | c.657C>T p.L219= | Silent (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- XK | c.39G>T p.L13= | Silent (SNP) | VAF 35/202 reads (17%) | catalogued as COSV101064747; called by muse, mutect2, varscan2
- AMPH | c.1182+1249G>T | Intron (SNP) | VAF 62/280 reads (22%) | called by muse, mutect2, varscan2
- ARID1B | c.2840+34C>T | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs767666829; called by muse, mutect2
- HSD3B2 | c.307+52_307+53dup | Intron (INS) | VAF 35/166 reads (21%) | called by mutect2, pindel, varscan2
- LITAF | c.*84G>A | 3'UTR (SNP) | VAF 53/262 reads (20%) | called by muse, mutect2, varscan2
- PDHA1 | c.510+61del | Intron (DEL) | VAF 40/201 reads (20%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.6675-44G>A | Intron (SNP) | VAF 96/342 reads (28%) | catalogued as COSV63989593; called by muse, mutect2, varscan2
- WRN | c.1432-50A>G | Intron (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
